Somatic mutation profile of tumor specimen ALCH-ADXE-TTP1-A (aliquot ALCH-ADXE-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADXE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 72.8 years (26,595 days).
Specimen ALCH-ADXE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6522dbdd-f461-4055-97a1-c69a41ead7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADXE-NB1-A (Blood Derived Normal), aliquot ALCH-ADXE-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1f9334-08fd-4e29-b1fd-68bdbe01d2dd

The open-access MAF lists 100 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Nonsense Mutation 8, Intron 4, 3'UTR 4, Splice Site 2, Frame Shift Del 2, 3'Flank 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 86/495 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763804037, CM970251, COSV100446243, COSV58683273, COSV58688196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP39 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 17/413 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as rs1464815156; called by muse, mutect2
- CCND1 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57119024, COSV57121599; called by muse, mutect2, varscan2
- CRELD1 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 101/487 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs759093681, COSV55976663; called by muse, mutect2, varscan2
- CRYBA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 33/443 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1255062174; called by muse, mutect2
- DEPDC5 | c.3264-8G>A | Splice Region (SNP) | VAF 45/533 reads (8%) | catalogued as rs1250227863; called by muse, mutect2
- EPRS1 | c.1743-1G>C p.X581_splice | Splice Site (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100859412; called by muse, mutect2
- F5 | c.4369C>A p.P1457T | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV63124034; called by muse, mutect2
- FLG | c.5983G>C p.E1995Q | Missense Mutation (SNP) | VAF 82/2312 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV100911378, COSV64247604; called by muse, mutect2
- FLG2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101165662; called by muse, mutect2
- FUT4 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2
- IFT57 | c.102del p.G35Afs*9 | Frame Shift Del (DEL) | VAF 83/451 reads (18%) | catalogued as rs753775167, COSV99197411; called by mutect2, pindel, varscan2
- LAMA4 | c.3841G>A p.V1281M (on ENST00000230538 / NM_001105206.3; = p.V1274M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs184696189, COSV57901140; called by muse, mutect2
- MGAM2 | c.4571G>A p.R1524H | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383566099, COSV72176926; called by muse, mutect2
- NR4A2 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 36/1262 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59894762; called by muse, mutect2
- OMP | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.595); catalogued as rs369608660; called by muse, mutect2
- OR2V1 | c.493A>G p.M165V | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV100265144; called by muse, mutect2, varscan2
- P2RY6 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 56/680 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs779583331; called by muse, mutect2
- PAQR4 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV51891717; called by muse, mutect2, varscan2
- RER1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 68/836 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as rs1557904518, COSV56581043, COSV99992011; called by muse, mutect2
- SERPINB6 | c.841A>G p.M281V (on ENST00000612421 / NM_001271823.2; = p.M262V on NM_004568.6) | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV59565898; called by muse, mutect2, varscan2
- SLC7A14 | c.1065C>A p.F355L | Missense Mutation (SNP) | VAF 26/754 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51592493; called by muse, mutect2
- SYNE1 | c.23196C>G p.S7732R (on ENST00000367255 / NM_182961.4; = p.S7661R on NM_033071.3) | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1554518143, COSV55134156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDG | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1406389640; called by muse, mutect2
- TP53 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.214); catalogued as COSV52660737, COSV52978302; called by muse, mutect2
- UBXN8 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1483914506; called by muse, mutect2
- USP8 | c.2190G>C p.E730D | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs770297801; called by muse, mutect2
- ABCC12 | c.1125_1128+12del p.X375_splice | Splice Site (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel
- ACTR6 | c.1040T>A p.V347D | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- AMPD3 | c.1570G>C p.D524H (on ENST00000396553 / NM_001025389.2; = p.D533H on NM_000480.3) | Missense Mutation (SNP) | VAF 23/602 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- APC | c.5504G>C p.R1835T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- ARMCX2 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BAHCC1 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CDH2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 40/694 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.258); called by muse, mutect2
- CLK2 | c.1385A>G p.Y462C (on ENST00000368361 / NM_001294339.2; = p.Y461C on NM_003993.4) | Missense Mutation (SNP) | VAF 28/689 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- COL6A6 | c.5096C>G p.S1699C | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- COQ2 | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2
- CRYZ | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- DPF1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FLG | c.4972G>T p.A1658S | Missense Mutation (SNP) | VAF 116/1021 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FOXP4 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 27/350 reads (8%) | called by muse, mutect2
- FRYL | c.6430C>G p.L2144V | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR158 | c.3487C>T p.Q1163* | Nonsense Mutation (SNP) | VAF 104/490 reads (21%) | called by muse, mutect2, varscan2
- HR | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- KDM3A | c.3803A>G p.E1268G | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF17 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 59/580 reads (10%) | called by muse, mutect2
- KIF21A | c.1807del p.E603Kfs*5 (on ENST00000361418 / NM_001378440.1; = p.E590Kfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, varscan2
- KMT2C | c.14044G>A p.E4682K | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- LIPE | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2
- MYT1 | c.2359A>T p.K787* | Nonsense Mutation (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- NOMO3 | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 44/670 reads (7%) | called by muse, mutect2
- NUTM1 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- PPP6R2 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 66/508 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRSS36 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSMD1 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RADX | c.1778T>G p.I593S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM42 | c.1367_1372del p.K456_S457del | In Frame Del (DEL) | VAF 26/148 reads (18%) | called by mutect2, pindel, varscan2
- SDE2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- SLC45A4 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 56/700 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- SLC6A2 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 106/700 reads (15%) | called by muse, mutect2, varscan2
- TENM4 | c.4707C>A p.F1569L | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- TRIM2 | c.2195C>T p.S732F (on ENST00000437508; = p.S759F on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TROAP | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2
- TRPC4AP | c.1517T>C p.L506S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSPOAP1 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 48/255 reads (19%) | called by muse, mutect2, varscan2
- TTC17 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2
- UBR5 | c.5854C>G p.Q1952E | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2
- WDR27 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 58/680 reads (9%) | called by muse, mutect2
- WRAP53 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- ZFYVE9 | c.542T>A p.F181Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2
- ZMAT2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ZNF324 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- ZSCAN2 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.077); called by muse, mutect2
- ARHGAP35 | c.3390C>T p.S1130= | Silent (SNP) | VAF 83/660 reads (13%) | catalogued as rs763081851; called by muse, mutect2, varscan2
- CBLN4 | c.505C>T p.L169= | Silent (SNP) | VAF 121/617 reads (20%) | catalogued as COSV50353759; called by muse, mutect2, varscan2
- FRG2 | c.471G>A p.K157= | Silent (SNP) | VAF 26/723 reads (4%) | called by muse, mutect2
- GCK | c.303G>T p.V101= | Silent (SNP) | VAF 36/1101 reads (3%) | catalogued as COSV61752711; called by muse, mutect2
- HTR2C | c.813G>A p.T271= | Silent (SNP) | VAF 36/599 reads (6%) | catalogued as COSV52203586, COSV52204062; called by muse, mutect2
- LPA | c.2754G>A p.P918= | Silent (SNP) | VAF 172/878 reads (20%) | catalogued as rs868248275, COSV60305916; called by muse, mutect2, varscan2
- LRCH1 | c.2073G>A p.T691= | Silent (SNP) | VAF 12/256 reads (5%) | catalogued as rs1373253030, COSV60846852; called by muse, mutect2
- LRRC45 | c.1464C>T p.I488= | Silent (SNP) | VAF 28/398 reads (7%) | called by muse, mutect2
- NEURL3 | c.354C>T p.L118= | Silent (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- PDS5B | c.2817T>C p.Y939= | Silent (SNP) | VAF 59/269 reads (22%) | catalogued as COSV59731171; called by muse, mutect2, varscan2
- SLC15A2 | c.1593G>T p.L531= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- SMC1A | c.675C>T p.L225= | Silent (SNP) | VAF 60/510 reads (12%) | catalogued as rs782182228; called by muse, varscan2
- STAR | c.105G>A p.L35= | Silent (SNP) | VAF 22/540 reads (4%) | called by muse, mutect2
- SYTL2 | c.1050T>C p.G350= | Silent (SNP) | VAF 36/363 reads (10%) | called by muse, mutect2, varscan2
- TDRD9 | c.1077C>G p.L359= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- TENM4 | c.4980C>G p.L1660= | Silent (SNP) | VAF 29/432 reads (7%) | called by muse, mutect2
- ZFAND2B | c.378C>T p.H126= | Silent (SNP) | VAF 93/524 reads (18%) | called by muse, mutect2, varscan2
- AKTIP | c.414+178C>G | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- ARHGAP42 | c.*3721A>T | 3'UTR (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- ATP1A2 | c.2840+46C>A | Intron (SNP) | VAF 63/530 reads (12%) | called by muse, mutect2, varscan2
- GRK4 | c.52+1251G>C | Intron (SNP) | VAF 69/795 reads (9%) | called by muse, mutect2
- KPNA4 | c.1032+358T>C | Intron (SNP) | VAF 48/750 reads (6%) | called by muse, mutect2
- LINC02691 | n.1367T>C | RNA (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949400 C>G | 3'Flank (SNP) | VAF 26/562 reads (5%) | called by muse, mutect2
- RGS4 | c.*42G>A | 3'UTR (SNP) | VAF 67/630 reads (11%) | called by muse, mutect2, varscan2
- XIAP | c.*1952A>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- XPO5 | c.*115G>C | 3'UTR (SNP) | VAF 18/652 reads (3%) | called by muse, mutect2
